Gene-level copy-number profile of tumor specimen C3N-02523-01 (profiled together with C3N-02523-02) from CPTAC case C3N-02523, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 61.4 years (22,428 days).
Specimen C3N-02523-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a821ef7b-57d5-41ea-ba75-6e61c2696c39.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02523-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/0c560154-81e0-4cc7-a429-e69c597ce02c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 558; copy number 1: 12,697; copy number 2: 39,640; copy number 3: 2,056; copy number 4: 2,764; copy number 5: 7; copy number 6: 49; copy number 7: 748; copy number 8: 280; copy number 9: 84; copy number 10: 27.

Homozygous deletions (total copy number 0; autosomes only): 46 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:69,280,475–69,423,164, 7 genes (within-gene range 0–1): UGT2B28, AC114786.3, AC114786.2, AC114786.4, UGT2B25P, AC108078.1, UGT2B24P.
- chr8:7,793,716–7,795,870, 1 gene: PRR23D3P.
- chr8:7,836,436–7,868,867, 2 genes: DEFB104A, SPAG11A.
- chr9:21,453,802–23,956,444, 36 genes: MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL365204.1, AL365204.2, AL365204.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,195 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:180,542,701–180,871,005, 10 genes, copy number 10 (within-gene range 4–10): U8, AC125618.1, RNU6-486P, AC068298.1, TTC14, CCDC39, CCDC39, CCDC39-AS1, AC108734.4, RN7SL229P.
- chr3:180,989,762–181,836,880, 1 gene, copy number 10 (within-gene range 4–10): SOX2-OT.
- chr3:181,231,737–198,123,232, 388 genes, copy number 6–10 (broad region; genes not listed).
- chr5:58,198–45,895,970, 679 genes, copy number 7–9 (broad region; genes not listed).
- chr8:7,539,628–7,592,916, 7 genes, copy number 5: PRR23D1, FAM90A6P, FAM90A7P, FAM90A21P, FAM90A22P, FAM90A23P, OR7E157P.
- chr8:7,715,443–7,749,044, 5 genes, copy number 10: FAM90A14P, FAM90A18P, FAM90A16P, FAM90A8P, FAM90A17P.
- chr8:7,811,720–7,829,053, 3 genes, copy number 8: DEFB107A, DEFB105A, DEFB106A.
- chr8:34,228,439–39,417,378, 94 genes, copy number 6–10 (broad region; genes not listed).
- chr8:39,522,976–39,928,790, 6 genes, copy number 7 (within-gene range 2–7): AC123767.1, ADAM18, ADAM2, AP005902.2, AP005902.1, IDO1.
- chr8:39,914,229–39,920,890, 2 genes, copy number 7 (within-gene range 2–7): AC007991.2, AC007991.4.

Autosomal genes at a single copy (total copy number 1): 10,353. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
